Surgical pathology report (de-identified scan), TCGA case TCGA-EJ-8474, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-EJ-8474-01A (Primary Tumor).

FINAL DIAGNOSIS:

PART 1: LYMPH NODES, RIGHT PELVIC, LYMPHADENECTOMY –

THIRTEEN LYMPH NODES, NO EVIDENCE OF METASTATIC CARCINOMA SEEN (0/13).

PART 2: LYMPH NODES, LEFT PELVIC, LYMPHADENECTOMY –

FIFTEEN LYMPH NODES, NO EVIDENCE OF METASTATIC CARCINOMA (0/15).

PART 3: PROSTATE, RADICAL PROSTATECTOMY –

- A. INVASIVE, POORLY DIFFERENTIATED PROSTATIC ADENOCARCINOMA, GLEASON SCORE 4 + 4= 8.
- B. TERTIARY GLEASON PATTERN 5 CARCINOMA IS SEEN AND ACCOUNTS FOR APPROXIMATELY 3% OF THE TOTAL TUMOR VOLUME.
- C. THE CARCINOMA MEASURES 2.4 CM IN GREATEST NODULAR DIMENSION AND CONSTITUTES APPROXIMATELY 40% OF THE TOTAL TISSUE EVALUATED.
- D. THE CARCINOMA INVOLVES BOTH THE RIGHT AND THE LEFT LOBES OF THE PROSTATE.
- E. EXTENSIVE ESTABLISHED EXTRACAPSULAR EXTENSION BY THE CARCINOMA IS SEEN.
- F. THE EXTRACAPSULAR EXTENSION IS SEEN IN THE LEFT LOBE OF THE PROSTATE AND IDENTIFIED IN THE POSTERIOR LEFT APEX, POSTERIOR LEFT MID, POSTERIOR LEFT BASE, AND ANTERIOR LEFT MID REGIONS.
- G. ALL INKED MARGINS OF RESECTION ARE FREE OF CARCINOMA.
- H. BILATERAL SEMINAL VESICLES, NO EVIDENCE OF CARCINOMA SEEN.
- I. PERINEURAL INVASION BY THE CARCINOMA IS IDENTIFIED.
- J. MULTIFOCAL HIGH GRADE PROSTATIC INTRA-EPITHELIAL NEOPLASIA (PIN) IS SEEN.
- K. TNM STAGE: T3a N0 MX.
- L. HISTOLOGIC GRADE G3-4 (POORLY DIFFERENTIATED/UNDIFFERENTIATED).

PART 4: PROSTATE, APICAL SOFT TISSUE, EXCISION –

BENIGN FIBROADIPOSE TISSUE, NO CARCINOMA SEEN.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY PROSTATE TUMORS

CLINICAL DATA:	PSA value: 7.9
INVASIVE CA IDENTIFIED?:	Yes
TUMOR HISTOLOGY:	Adenocarcinoma NOS
PRIMARY GLEASON GRADE:	4
SECONDARY GLEASON GRADE:	4
GLEASON SUM SCORE:	8
GLEASON 4/5 PERCENTAGE:	85%
WEIGHT OF PROSTATE:	52.74gm
TUMOR SIZE:	Maximum dimension: 2.4 cm
LOBE LATERALITY:	Right and Left Lobes
PERCENT OF SPECIMEN INVOLVED BY TUMOR:	> 25%
MULTIFOCAL DISEASE:	Yes
HIGH GRADE PIN:	Yes - NOS
EXTRAPROSTATIC EXTENSION:	Yes - Established (> 0.8mm)
PERINEURAL INVASION:	Yes
ANGIOLYMPHATIC INVASION:	No
SEMINAL VESICLE INVASION:	No
SURGICAL MARGIN INVOLVEMENT:	All surgical margins free of tumor
RESIDUAL TUMOR:	R0
LYMPH NODES EXAMINED:	28
LYMPH NODES POSITIVE:	0
T STAGE, PATHOLOGIC:	pT3a
N STAGE, PATHOLOGIC:	pN0
M STAGE, PATHOLOGIC:	pMX
HISTOLOGIC GRADE:	G3-4, Poorly differentiated/undifferentiated

Source: NCI Genomic Data Commons file 2d52f087-0533-4aed-9a5a-35769b20f085 (TCGA-EJ-8474.F68BB2BF-D38C-4D21-91CD-E714C71A6FF5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).